Gene-level copy-number profile of tumor specimen ALCH-B37J-TTP1-A from ALCHEMIST case ALCH-B37J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.4 years (27,902 days).
Specimen ALCH-B37J-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 85b83d1d-f49a-440f-8aa5-0cfd9e8891f0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B37J-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/004c7ab9-3739-4b5b-9c1b-52672e4ff0d7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 1,529; copy number 2: 56,358; copy number 3: 373; copy number 4: 35; copy number 5: 3; copy number 6: 2; copy number 8: 1; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:916,865–921,016, 1 gene: LINC02593.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–2): AL139423.1.
- chr1:16,014,028–16,034,050, 2 genes: HSPB7, CLCNKA.
- chr1:248,623,557–248,635,091, 1 gene: OR2T11.
- chr2:131,527,675–131,536,988, 2 genes: CCDC74A, MED15P4.
- chr4:7,310,450–7,310,524, 1 gene (within-gene range 0–1): MIR4798.
- chr5:191,495–196,341, 2 genes: LRRC14B, AC021087.4.
- chr6:34,537,802–34,556,333, 1 gene: SPDEF.
- chr6:170,254,334–170,279,887, 3 genes: AL109910.1, AL109910.2, LINC01624.
- chr9:126,589,594–126,613,700, 1 gene: AL161908.1.
- chr9:127,716,079–127,731,590, 1 gene (within-gene range 0–2): TTC16.
- chr9:129,004,502–129,028,331, 2 genes (within-gene range 0–2): AL592211.1, SH3GLB2.
- chr10:72,053,294–72,054,037, 1 gene: AC022392.1.
- chr11:818,914–832,883, 3 genes (within-gene range 0–1): PNPLA2, AP006621.1, CRACR2B.
- chr11:837,356–842,529, 1 gene (within-gene range 0–1): POLR2L.
- chr11:856,880–859,795, 1 gene (within-gene range 0–2): AP006623.1.
- chr11:76,186,325–76,210,736, 2 genes: WNT11, AP000785.1.
- chr11:134,378,504–134,412,242, 1 gene: B3GAT1.
- chr12:124,529,722–124,562,283, 5 genes (within-gene range 0–2): AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6.
- chr12:131,857,420–131,864,538, 1 gene: AC131009.2.
- chr14:100,538,939–100,540,409, 1 gene (within-gene range 0–2): AL845552.2.
- chr15:25,180,497–25,227,190, 24 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31.
- chr15:25,241,746–25,241,827, 1 gene (within-gene range 0–2): SNORD115-39.
- chr16:2,817,180–2,842,744, 4 genes: PRSS21, EIF1P4, ZG16B, PRSS30P.
- chr16:4,616,493–4,690,974, 5 genes (within-gene range 0–2): MGRN1, RN7SL850P, AC023830.1, Metazoa_SRP, MIR6769A.
- chr16:83,929,796–83,931,223, 1 gene (within-gene range 0–1): AC009119.2.
- chr16:87,830,023–87,869,507, 3 genes: SLC7A5, MIR6775, AC126696.2.
- chr18:8,471,831–8,472,128, 1 gene: RN7SL50P.
- chr19:11,113,474–11,113,534, 1 gene (within-gene range 0–2): MIR6886.
- chr20:25,284,915–25,285,588, 1 gene (within-gene range 0–2): AL121772.3.
- chr22:18,951,934–18,959,512, 1 gene: AC007326.2.
- chr22:42,132,543–42,149,455, 4 genes (within-gene range 0–2): AC254562.1, AC254562.2, AC254562.3, CYP2D7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:50,312,324–50,335,558, 2 genes, copy number 6 (within-gene range 2–6): DMAC2L, AL359397.2.
- chr15:20,531,856–20,541,800, 1 gene, copy number 8: GOLGA6L6.
- chr15:32,313,126–32,315,654, 1 gene, copy number 19: AC139426.1.
- chr15:32,398,956–32,435,233, 3 genes, copy number 5 (within-gene range 2–5): AC135983.1, ULK4P1, U8.

Autosomal genes at a single copy (total copy number 1): 1,529. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
